Somatic mutation profile of tumor specimen TCGA-A3-3365-01A (aliquot TCGA-A3-3365-01A-01W-0886-08) from TCGA case TCGA-A3-3365, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 46.3 years (16,915 days).
Specimen TCGA-A3-3365-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f19dc414-880a-46a9-885b-503f15b40a0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3365-11A (Solid Tissue Normal), aliquot TCGA-A3-3365-11A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18012079-216a-41fc-87f8-dff8ea43c840

The open-access MAF lists 60 somatic variants for this specimen: 43 protein-altering or splice-affecting, 14 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 14, Nonsense Mutation 3, Frame Shift Ins 2, Intron 1, Frame Shift Del 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSL1 | c.1187G>T p.R396M | Missense Mutation (SNP) | VAF 64/518 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.316); catalogued as COSV55662676; called by muse, varscan2
- ADAMTS16 | c.1517A>T p.K506I | Missense Mutation (SNP) | VAF 19/554 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV56989478; called by muse, mutect2
- ADGRG6 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.974); catalogued as COSV51592244; called by muse, mutect2, varscan2
- ANKRD42 | c.47C>T p.T16I | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs760713904, COSV52615828; called by muse, mutect2, varscan2
- BAZ1B | c.4310T>C p.V1437A | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT tolerated (0.81); PolyPhen benign (0.01); catalogued as COSV59991122; called by muse, mutect2
- BICD1 | c.312C>A p.Y104* | Nonsense Mutation (SNP) | VAF 10/227 reads (4%) | catalogued as COSV55679373; called by muse, mutect2
- BID | c.510C>G p.N170K (on ENST00000317361 / NM_197966.2; = p.N124K on NM_001196.4) | Missense Mutation (SNP) | VAF 76/121 reads (63%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV58006836; called by muse, mutect2, varscan2
- BRCA2 | c.2494G>A p.E832K | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.755); catalogued as COSV66453672, COSV66458383; called by muse, mutect2, varscan2
- C8orf34 | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 7/155 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61379946; called by muse, mutect2
- CBLC | c.637G>C p.V213L | Missense Mutation (SNP) | VAF 57/97 reads (59%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as COSV54322587, COSV54323208; called by muse, mutect2, varscan2
- CNKSR2 | c.2323C>A p.P775T | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54256116, COSV99667839; called by muse, mutect2, varscan2
- COPS4 | c.210C>A p.C70* | Nonsense Mutation (SNP) | VAF 21/93 reads (23%) | catalogued as COSV52314937; called by muse, varscan2
- CTNND2 | c.325G>C p.G109R | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV58888796, COSV58926836; called by muse, mutect2, varscan2
- CYP4A11 | c.256T>C p.C86R | Missense Mutation (SNP) | VAF 49/362 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.56); catalogued as COSV60223501; called by muse, mutect2, varscan2
- DBNL | c.893G>T p.G298V (on ENST00000448521 / NM_001014436.3; = p.G299V on NM_014063.7) | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV51977828; called by muse, mutect2
- DIO1 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 27/242 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99300751; called by muse, mutect2, varscan2
- EVA1C | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV55824110; called by muse, mutect2
- GCN1 | c.6042G>T p.L2014F | Missense Mutation (SNP) | VAF 40/1353 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56107762; called by muse, mutect2
- GCNT4 | c.880dup p.H294Pfs*2 | Frame Shift Ins (INS) | VAF 12/106 reads (11%) | catalogued as rs768450027; called by mutect2, varscan2
- HAUS6 | c.1721C>T p.P574L | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65839989; called by mutect2, varscan2
- JAKMIP2 | c.1892A>C p.D631A | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV54604439; called by muse, mutect2, varscan2
- JKAMP | c.199C>G p.P67A (on ENST00000554271 / NM_001284201.1; = p.P53A on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 166/662 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV54199466; called by muse, varscan2
- JUP | c.1459A>C p.K487Q | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV60278007; called by muse, mutect2, varscan2
- KMT2D | c.785C>A p.A262D | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs1441499895, COSV56439462; called by muse, varscan2
- MICU1 | c.1297T>C p.F433L (on ENST00000361114 / NM_001195518.2; = p.F439L on NM_006077.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/247 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.831); catalogued as COSV63144860; called by muse, mutect2, varscan2
- MR1 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as COSV51580836, COSV99031895; called by muse, mutect2, varscan2
- MYO3A | c.4712G>A p.C1571Y | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0); catalogued as COSV56330778; called by muse, mutect2, varscan2
- NKTR | c.1847dup p.S617Ffs*15 | Frame Shift Ins (INS) | VAF 24/176 reads (14%) | catalogued as rs763440516; called by mutect2, varscan2
- OR52A1 | c.693G>T p.L231F | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61092416; called by muse, mutect2
- PAQR3 | c.775C>A p.P259T | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55009756; called by muse, mutect2
- PLCH1 | c.539G>A p.R180Q (on ENST00000340059 / NM_001130960.2; = p.R192Q on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 104/497 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs775027679, COSV58197230; called by muse, mutect2, varscan2
- PRKDC | c.1030C>T p.Q344* | Nonsense Mutation (SNP) | VAF 4/80 reads (5%) | catalogued as COSV58052250; called by muse, mutect2
- PSMD6 | c.351A>C p.K117N | Missense Mutation (SNP) | VAF 98/345 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV55759806; called by muse, mutect2, varscan2
- SIPA1L2 | c.356G>C p.S119T | Missense Mutation (SNP) | VAF 49/250 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.017); catalogued as COSV53390407; called by muse, mutect2, varscan2
- STAT2 | c.2455G>A p.G819S | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV57336052; called by muse, mutect2, varscan2
- TASOR2 | c.5012T>G p.V1671G | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV60167451; called by muse, mutect2, varscan2
- TBX1 | c.1027G>T p.D343Y | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); catalogued as COSV61548505; called by muse, mutect2, varscan2
- VAPB | c.419T>C p.I140T | Missense Mutation (SNP) | VAF 86/251 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV55667575; called by muse, mutect2, varscan2
- ZMYM3 | c.3619G>A p.V1207I | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.407); catalogued as COSV58737863; called by muse, mutect2
- ZNF292 | c.3098T>A p.V1033E | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.123); catalogued as COSV60539414; called by muse, mutect2, varscan2
- DIO1 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MLF2 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 7/210 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.436); called by muse, mutect2
- PBRM1 | c.513del p.T172Qfs*2 | Frame Shift Del (DEL) | VAF 137/881 reads (16%) | called by mutect2, pindel, varscan2
- ABCC11 | c.2835C>A p.S945= | Silent (SNP) | VAF 8/212 reads (4%) | catalogued as COSV62323071; called by muse, mutect2
- DTX3 | c.1043G>A p.*348= | Silent (SNP) | VAF 14/180 reads (8%) | catalogued as COSV54086546; called by muse, mutect2
- FN1 | c.6081G>T p.G2027= | Silent (SNP) | VAF 71/184 reads (39%) | catalogued as COSV60552796; called by muse, mutect2, varscan2
- KDM8 | c.135G>A p.V45= | Silent (SNP) | VAF 47/272 reads (17%) | catalogued as COSV53729689; called by muse, mutect2, varscan2
- KMT2D | c.786C>T p.A262= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs368315432; called by muse, varscan2
- KRT85 | c.1317C>A p.G439= | Silent (SNP) | VAF 157/1166 reads (13%) | catalogued as COSV57736865; called by muse, varscan2
- MICU2 | c.1209A>G p.Q403= | Silent (SNP) | VAF 23/119 reads (19%) | catalogued as rs762908813, COSV66673994; called by muse, mutect2, varscan2
- MLXIPL | c.2349C>T p.N783= | Silent (SNP) | VAF 8/182 reads (4%) | catalogued as rs185020196, COSV57668164; called by muse, mutect2
- MOCOS | c.1440C>A p.A480= | Silent (SNP) | VAF 20/203 reads (10%) | catalogued as COSV54343377; called by muse, mutect2
- PCDHGC5 | c.744T>A p.R248= | Silent (SNP) | VAF 170/524 reads (32%) | catalogued as COSV52751764; called by muse, mutect2, varscan2
- SLC9A9 | c.867G>T p.G289= | Silent (SNP) | VAF 44/458 reads (10%) | catalogued as rs1215314136, COSV57227117; called by muse, mutect2
- SLCO5A1 | c.1827G>A p.V609= | Silent (SNP) | VAF 16/572 reads (3%) | catalogued as COSV52659406; called by muse, mutect2
- SUPT20HL2 | c.1035T>C p.C345= | Silent (SNP) | VAF 9/63 reads (14%) | called by mutect2, varscan2
- TASOR | c.4368T>C p.H1456= (on ENST00000355628 / NM_001365636.2; = p.H1080= on NM_015224.3) | Silent (SNP) | VAF 12/99 reads (12%) | called by mutect2, varscan2
- CR1 | c.487+12041T>C | Intron (SNP) | VAF 13/132 reads (10%) | called by muse, mutect2
- DCHS2 | n.2264G>T | RNA (SNP) | VAF 7/75 reads (9%) | called by muse, mutect2
- UVSSA | c.*8707G>A | 3'UTR (SNP) | VAF 32/186 reads (17%) | catalogued as COSV61348949; called by muse, varscan2
